Somatic mutation profile of tumor specimen TARGET-10-PATCDM-40A (aliquot TARGET-10-PATCDM-40A-01D) from TARGET case TARGET-10-PATCDM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,192 days).
Specimen TARGET-10-PATCDM-40A: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 895f9859-5f48-47dd-9823-9b8a450d9f94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATCDM-10A (Blood Derived Normal), aliquot TARGET-10-PATCDM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60e7c345-de1f-460f-9db8-35122e8387b4

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CXXC1 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV53275262; called by muse, mutect2, varscan2
- EVI2A | c.700C>G p.Q234E | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV55986331; called by muse, mutect2, varscan2
- ARFGAP1 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- USP7 | c.2384_2386del p.D795del | In Frame Del (DEL) | VAF 73/181 reads (40%) | called by mutect2, pindel, varscan2
- SIPA1 | c.3117C>T p.A1039= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as rs780236671; called by muse, mutect2, varscan2
- TBCD | c.3282-108A>C | Intron (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
